Surgical pathology report (de-identified scan), TCGA case TCGA-97-8175, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8175-01A (Primary Tumor).

[page 1 of 10]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. F/S LUNG, LEFT UPPER LOBE WEDGE
2. LEVEL 5 LYMPH NODE, LEFT
3. COMPLETION LEFT UPPER LOBECTOMY
4. LEVEL 9 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

Reason For Addendum #4: Biomarker Report

DIAGNOSIS:

1,3. LUNG, LEFT UPPER LOBE: WEDGE RESECTION AND COMPLETION LOBECTOMY

- **ADENOCARCINOMA, SOLID PREDOMINANT (3.2 CM), SEE NOTE.**
- **THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.**
- **SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).**

Note: The tumor consists of solid (90%) and micropapillary (10%) components and measures 3.2 cm in greatest dimension microscopically. Results of mutational studies will be reported in addenda.

2. LYMPH NODE, LEVEL 5: BIOPSY

- **TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).**

4. LYMPH NODE, LEVEL 9: BIOPSY

- **TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).**

Specimens: 1: F/S LUNG, LEFT UPPER LOBE WEDGE

2: LEVEL 5 LYMPH NODE, LEFT

3: COMPLETION LEFT UPPER LOBECTOMY

4: LEVEL 9 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)
left upper lobe

[page 2 of 10]
Procedure: Lobectomy

Specimen Integrity: Intact

Specimen Laterality: Left

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Solid adenocarcinoma

Histologic Grade: G3: Poorly differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

3.2cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

11

Number Involved

0

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED]

with a 4 cm LUL mass.

MACROSCOPIC DESCRIPTION:

The specimen is received in four parts, each labeled with the

[page 3 of 10]
patient's name.

1. Part one is received fresh, labeled 'left upper lobe wedge at 084 b'. It consists of a pre-incised wedge biopsy of the lung measuring 9 x 3.5 x 2 cm. The stapled line measures 9 cm in length. The stapled line is shaved and the pleura around is inked black. At the pre-incised area there is a grey-white firm nodule measuring 2 x 1.1 x 1.1 cm located 0.4 cm from the stapled line margin. The remainder of the parenchyma is pink-red and crepitant. Frozen section performed on the nodule and resubmitted for permanent section. Representative sections are submitted.

2. Part two is received in saline, labeled 'level 5 lymph node'. It consists of two pieces of tan-brown soft tissue measuring 1.0 x 0.8 x 0.3 cm and 0.4 x 0.3 x 0.2 cm. Entirely submitted.

3. Part three is received fresh, labeled 'completion left upper lobectomy'. It consists of a 176 gram left upper lobe of the lung measuring 23 x 6.5 x 4 cm. There are two staple lines at the medial aspect of the specimen measuring 11 cm and 11.5 cm. The staples are removed and this margin is inked black. The pleural surface is inked blue. The specimen is serially sectioned from superior to inferior. There is no grossly palpable mass or lesion identified. Representative sections are submitted.

4. Part four is received in saline, labeled 'level 9 lymph node'. It consists of a piece of tan-brown soft tissue measuring 0.9 x 0.4 x 0.2 cm. Entirely submitted.

SUMMARY OF SECTIONS:

- 1A frozen section remaining of the nodule
- 1B-1E remaining of the nodule
- 1F stapled line margin
- 1G random section of the parenchyma
- 2A in toto
- 3A bronchial margins
- 3B vessel margins
- 3C possible hilar lymph nodes
- 3D one bisected hilar lymph node
- 3E-3J representative sections, including entire hilar region
- 4A in toto

SPECIAL PROCEDURES:

[page 4 of 10]
INTRA - OPERATIVE CONSULTATION:

1. Lung, left upper lobe, wedge resection:
- Adenocarcinoma

ADDENDUM # 1 FOR MOLECULAR TESTS:

EGFR, KRAS and ALK (FISH) was sent on 1 [REDACTED] for patient [REDACTED]. The test is to be performed on tissue from case [REDACTED] date [REDACTED]. The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 1C appropriate to the specifications of the ordered molecular analysis. 1 H& E and 9 unstained slides were prepared and forwarded to [REDACTED] where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by

[REDACTED]

Electronically signed

[REDACTED]

ADDENDUM #2:

EGFR Mutation Analysis

[page 5 of 10]
[REDACTED]

Referring Physician: [REDACTED]

Body Site: Left upper lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 80% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is

[page 6 of 10]
selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[REDACTED]

DISCLAIMER:

This test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]
[REDACTED]

[REDACTED]

Addendum #2 performed by

[REDACTED]
Electronically [REDACTED]

ADDENDUM #3:

[page 7 of 10]
MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

Referring Physician: [REDACTED]

Body Site: Left upper lobe of lung

Specimen Type: Slides

Clinical Data: Adenocarcinoma

RESULTS: Wild-type gene.

INTERPRETATION:

No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single

[page 8 of 10]
nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

[REDACTED]

[REDACTED]

Addendum #3 performed by

[REDACTED]

[page 9 of 10]
ADDENDUM 3:

[REDACTED]

Fluorescence In-Situ Hybridization (FISH)

[REDACTED]

Body Site: Left upper lobe of Lung

Clinical Data: Adenocarcinoma

INTERPRETATION:

Negative for a rearrangement involving the ALK gene.

Probe #Nuclei Examined % Positive Nuclei %

Control values

2p23(ALK)V 100 0 <15.0

A total of 100 cells were scored.

FINDINGS: FISH was performed on paraffin embedded tissue sections using dual color break-apart probe [REDACTED] to the ALK gene at 2p23. This probe flanks the entire gene. If a rearrangement involving ALK is present, inversion or translocation, one of the two probe signals separates as one red (orange) and one green signal. In this specimen, separated signals were present in 0.5% of the nuclei scored. Based on laboratory validation data, these results are within the normal limits.

COMMENTS: Three to four copies of ALK were observed in 27.0% of cells. This gain of intact ALK fusion hybridization signals represents an aneuploid population with extra copies of chromosomes 2/2p ALK region. Additional copies of ALK are not uncommon in NSCLCs, although the significance of extra copies of the ALK gene in lung carcinoma is unclear at this time ([REDACTED])

ISCN RESULTS: nuc ish(ALKx3 4)[42/100]

This test was developed and its performance characteristics determined by [REDACTED] It has not been cleared or

[page 10 of 10]
approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing.

[REDACTED]

Electronically signed by: [REDACTED] Date:

[REDACTED]

[REDACTED]

Addendum #4 performed by

[REDACTED]

Electronically signed

[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file c90821dd-cc44-4c29-af7b-c4efe7afb556 (TCGA-97-8175.19C71BBA-794D-4245-BBD8-536740912C9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).